Somatic mutation profile of tumor specimen ASCProject_0003_T1_WES (aliquot ASCProject_0003_T1_WES_1) from CMI case ASCProject_0003, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.8 years (14,180 days).
Specimen ASCProject_0003_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 026e4cd1-407f-474b-bb87-e41480ff995c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0003_SALIVA (Saliva), aliquot ASCProject_0003_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96da2160-856b-4c31-9f28-ab608db28fb0

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3132T>A p.N1044K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2
- IL10 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs780612967; called by muse, mutect2
- RASA1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57194722, COSV99171476; called by muse, mutect2
- USP21 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV57089453; called by muse, mutect2, varscan2
- ADGRL4 | c.1748T>G p.L583R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CES1 | c.680T>A p.V227D | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COPS3 | c.1157T>C p.L386P | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GNAI2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP2 | c.2471del p.A824Efs*27 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by pindel, varscan2
- RPS6KA5 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, varscan2
- MTUS2 | c.3240G>A p.R1080= (on ENST00000612955 / NM_001366650.1; = p.R59= on NM_015233.6) | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- TBCE | c.93C>T p.P31= | Silent (SNP) | VAF 13/220 reads (6%) | catalogued as rs1266066372, COSV64005743; called by muse, mutect2
- ADK | c.*171C>T | 3'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- DCHS2 | n.3904C>T | RNA (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
